Somatic mutation profile of tumor specimen MBCProject_0589_T1A_WES (aliquot MBCProject_0589_T1A_WES_1) from CMI case MBCProject_0589, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 50.2 years (18,337 days).
Specimen MBCProject_0589_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efaac110-53e5-4c4a-b73f-5dc035900cf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0589_SALIVA (Saliva), aliquot MBCProject_0589_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38bf4eea-b907-405e-8bd1-796d084e2f81

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Nonsense Mutation 1, 5'Flank 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP35 | c.4105C>T p.H1369Y | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1249121166; called by muse, mutect2
- LAMA1 | c.3223G>T p.D1075Y | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV67539637; called by muse, mutect2
- LRRC41 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs1364789070; called by muse, mutect2
- PCDH15 | c.4924G>A p.A1642T (on ENST00000644397 / NM_001354429.2; = p.A1584T on NM_001142771.2) | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as rs748762813, COSV64685666; called by muse, mutect2
- ALDH1L1 | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- CACNA1I | c.5085G>T p.E1695D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- CPB1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- EGF | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ITGAD | c.2543T>A p.V848E | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.02); called by muse, mutect2
- KIF11 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KPNA2 | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RADX | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.981); called by muse, mutect2
- RARA | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SFRP1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- STK11 | c.995delinsTT p.W332Ffs*28 | Frame Shift Ins (INS) | VAF 7/83 reads (8%) | called by mutect2*, pindel
- ZNF595 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.215); called by muse, mutect2
- ZSWIM4 | c.301A>C p.T101P | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.125); called by muse, mutect2
- IFI16 | c.2235G>A p.G745= (on ENST00000295809 / NM_001364867.2; = p.G689= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as COSV55537069; called by muse, mutect2, varscan2
- LENG8 | c.2094C>T p.H698= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs749470547; called by muse, mutect2
- MAGIX | c.390C>T p.R130= | Silent (SNP) | VAF 21/221 reads (10%) | catalogued as rs782308591, COSV100891932; called by muse, mutect2
- PBX3 | c.408G>A p.A136= | Silent (SNP) | VAF 34/386 reads (9%) | catalogued as rs777642477, COSV100655307; called by muse, mutect2
- RAG1 | c.2775G>A p.T925= | Silent (SNP) | VAF 46/470 reads (10%) | catalogued as rs777246735, COSV55025926; called by muse, mutect2
- RNF14 | c.1395C>T p.D465= | Silent (SNP) | VAF 28/368 reads (8%) | catalogued as rs1331628586; called by muse, mutect2
- TTN | c.44259T>C p.D14753= (on ENST00000591111; = p.D7329= on NM_003319.4) | Silent (SNP) | VAF 27/702 reads (4%) | catalogued as rs1168622734; called by muse, mutect2
- ZBTB14 | c.777C>T p.A259= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as rs377633263; called by muse, mutect2
- ZBTB16 | c.1875C>T p.N625= | Silent (SNP) | VAF 16/315 reads (5%) | catalogued as rs566297803, COSV60089798; called by muse, mutect2
- FTH1 | chr11:61968298 C>T | 5'Flank (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- RPAIN | c.314-526T>C | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs1411912416; called by muse, mutect2
